Gene-level copy-number profile of tumor specimen TCGA-A7-A13G-01B from TCGA case TCGA-A7-A13G, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.3 years (28,969 days).
Specimen TCGA-A7-A13G-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.defdce72-fa52-4bbc-8f34-b3e9e1c3f12d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A13G-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 372 have no estimate.
https://portal.gdc.cancer.gov/files/187b4050-aadb-4643-ba4c-ba06822458df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 561; copy number 1: 3,230; copy number 2: 51,034; copy number 3: 3,268; copy number 4: 1,889; copy number 5: 167; copy number 6: 33; copy number 7: 11; copy number 8: 1; copy number 11: 19; copy number 13: 5; copy number 16: 1; copy number 17: 31; copy number 24: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A13G-01A-11D-A13J-01): tumor purity 0.86, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,838,523–33,840,140, 1 gene: HSPD1P14.
- chr3:183,447,608–183,463,201, 6 genes (within-gene range 0–2): LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3.
- chr3:185,076,838–185,153,060, 1 gene (within-gene range 0–2): C3orf70.
- chr4:8,005,301–8,023,126, 2 genes: MIR95, AC097381.3.
- chr4:42,151,028–42,268,110, 1 gene (within-gene range 0–2): AC111006.1.
- chr5:82,968,888–82,977,153, 1 gene: ST13P12.
- chr5:102,664,610–102,726,598, 1 gene (within-gene range 0–2): AC099487.2.
- chr5:175,658,030–175,710,756, 1 gene (within-gene range 0–2): HRH2.
- chr6:135,807,148–135,808,466, 1 gene: AL133319.1.
- chr7:126,533,665–126,537,295, 1 gene: AC002057.1.
- chr7:143,935,166–143,936,279, 1 gene: OR2F2.
- chr9:109,196,201–109,196,309, 1 gene: RNU6-984P.
- chr9:111,631,334–111,670,229, 2 genes (within-gene range 0–2): DNAJC25, DNAJC25-GNG10.
- chr9:124,031,624–124,032,524, 1 gene: AC006450.2.
- chr10:5,638,867–5,666,595, 1 gene: ASB13.
- chr11:5,580,877–5,581,884, 1 gene: OR52B6.
- chr12:911,736–990,053, 1 gene (within-gene range 0–2): RAD52.
- chr12:95,943,331–95,968,720, 1 gene (within-gene range 0–1): AMDHD1.
- chr15:25,135,642–25,170,804, 4 genes: PWAR1, SNORD115, DMAC1P1, SNORD115-1.
- chr16:55,425,574–55,426,130, 1 gene: AC007336.2.
- chr19:29,838,532–29,841,818, 1 gene: AC008798.2.
- chr19:53,992,288–54,063,953, 3 genes (within-gene range 0–2): CACNG6, AC012314.9, VSTM1.
- chr20:1,722,045–1,722,537, 1 gene: AL109809.2.
- chr22:19,630,750–19,667,555, 2 genes: AC000077.1, AC000067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 269 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,983,192–162,039,567, 2 genes, copy number 6 (within-gene range 3–6): OLFML2B, AL590408.1.
- chr1:162,146,709–162,175,243, 2 genes, copy number 6: AL450163.1, MIR4654.
- chr1:201,134,772–201,171,574, 1 gene, copy number 6 (within-gene range 4–6): TMEM9.
- chr1:201,719,508–201,719,627, 1 gene, copy number 24: MIR5191.
- chr2:88,857,161–89,085,787, 22 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15.
- chr2:128,580,491–128,581,576, 1 gene, copy number 16: AC012451.1.
- chr3:41,194,741–41,260,096, 1 gene, copy number 5 (within-gene range 0–5): CTNNB1.
- chr4:8,066,528–8,067,724, 1 gene, copy number 13: AC097381.2.
- chr5:24,786,842–24,787,024, 1 gene, copy number 7: BTG4P1.
- chr5:76,170,930–76,174,183, 2 genes, copy number 6: AC113404.2, AC113404.3.
- chr5:136,857,628–136,858,342, 1 gene, copy number 6: ANKRD49P3.
- chr6:5,997,999–6,007,605, 1 gene, copy number 8: NRN1.
- chr6:31,479,973–31,511,124, 3 genes, copy number 13: MICB-DT, MICB, Y_RNA.
- chr7:13,339,201–13,365,049, 1 gene, copy number 6 (within-gene range 1–6): AC011287.2.
- chr7:14,985,378–15,562,015, 3 genes, copy number 5: GTF3AP5, AC006458.1, AGMO.
- chr7:54,721,724–55,211,628, 6 genes, copy number 5 (within-gene range 3–5): AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr7:69,594,793–74,760,692, 87 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:7,298,744–7,355,359, 1 gene, copy number 7 (within-gene range 2–7): FAM66B.
- chr8:7,332,387–7,385,558, 5 genes, copy number 7: USP17L1, USP17L4, AC130360.1, ZNF705G, DEFB108C.
- chr8:38,223,957–38,275,558, 2 genes, copy number 7 (within-gene range 2–7): AC084024.4, DDHD2.
- chr8:54,354,168–54,355,118, 1 gene, copy number 6: AC027250.1.
- chr8:96,222,947–96,239,149, 2 genes, copy number 5: UQCRB, AP003465.1.
- chr9:135,521,438–135,526,540, 1 gene, copy number 13: LCN1.
- chr10:43,523,256–43,525,217, 1 gene, copy number 6 (within-gene range 2–6): AL450326.2.
- chr13:24,517,794–24,541,720, 2 genes, copy number 7: AL359538.4, AL359538.3.
- chr13:55,062,945–55,161,490, 2 genes, copy number 5 (within-gene range 2–5): LINC02335, AL139038.1.
- chr14:61,556,273–61,570,653, 1 gene, copy number 11 (within-gene range 2–11): LINC01303.
- chr14:105,881,034–106,443,583, 97 genes, copy number 5–17 (broad region; genes not listed).
- chr15:25,054,210–25,081,378, 14 genes, copy number 11: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.
- chr16:1,911,475–1,961,975, 4 genes, copy number 11 (within-gene range 3–11): HS3ST6, MSRB1, RPL3L, NDUFB10.

Autosomal genes at a single copy (total copy number 1): 3,230. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
